Somatic mutation profile of tumor specimen MP2PRT-PARPUZ-TMP1-A (aliquot MP2PRT-PARPUZ-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARPUZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (722 days).
Specimen MP2PRT-PARPUZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 689a1f0e-82ca-44ca-a536-59c3117ff0f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPUZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPUZ-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9c0e342-fb97-41de-bc72-d1ac9df5c22f

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 2, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRINP1 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 231/621 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.539); catalogued as rs151314025, COSV99078587; called by muse, mutect2, varscan2
- ETV1 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 84/497 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs753053339; called by muse, mutect2, varscan2
- KCNQ3 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 146/420 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.298); catalogued as rs143683496; ClinVar: benign / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- PERP | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 84/533 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as COSV69827607; called by muse, varscan2
- TAL1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 36/991 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs767980860, COSV53749056, COSV99595866; called by muse, mutect2
- BEST4 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 279/712 reads (39%) | called by muse, mutect2, varscan2
- EEF2 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 44/602 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- EPOR | c.1220C>G p.S407* | Nonsense Mutation (SNP) | VAF 95/658 reads (14%) | called by muse, mutect2, varscan2
- GPR33 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 29/407 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- TMEM260 | c.697T>C p.Y233H | Missense Mutation (SNP) | VAF 94/529 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRGJP1 | chr7:38276313 del TGGTATCACACCGGTCT | Missense Mutation (DEL) | VAF 57/109 reads (52%) | called by mutect2, pindel, varscan2
- CDON | c.3813C>A p.G1271= (on ENST00000392693 / NM_001243597.2; = p.G1248= on NM_016952.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 103/594 reads (17%) | called by muse, mutect2, varscan2
- UBE4A | c.2643G>A p.L881= (on ENST00000252108 / NM_001204077.2; = p.L888= on NM_004788.4) | Silent (SNP) | VAF 106/539 reads (20%) | catalogued as COSV52804157; called by muse, mutect2, varscan2
- ATP6V0B | c.67+41G>A | Intron (SNP) | VAF 48/1164 reads (4%) | called by muse, mutect2
